Somatic mutation profile of tumor specimen TCGA-D8-A1XK-01A (aliquot TCGA-D8-A1XK-01A-21D-A14K-09) from TCGA case TCGA-D8-A1XK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.0 years (20,092 days).
Specimen TCGA-D8-A1XK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76380ead-09ca-411d-a628-928190639175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XK-10A (Blood Derived Normal), aliquot TCGA-D8-A1XK-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6958cfa-e1da-4573-9665-497bd132c3db

The open-access MAF lists 1,145 somatic variants for this specimen: 894 protein-altering or splice-affecting, 235 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 706, Silent 235, Frame Shift Del 85, Splice Site 53, Frame Shift Ins 18, Nonsense Mutation 17, Splice Region 11, RNA 5, Intron 5, 5'Flank 3, 3'UTR 3, Nonstop Mutation 2.

Variants (750 of 1,145; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- DNAH5 | c.3598+2T>C p.X1200_splice | Splice Site (SNP) | VAF 44/190 reads (23%) | catalogued as rs981267400, COSV99454608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMUT | c.753+2T>A p.X251_splice | Splice Site (SNP) | VAF 23/76 reads (30%) | catalogued as rs796052006, CS060549, COSV99222601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3974+2T>C p.X1325_splice | Splice Site (SNP) | VAF 34/84 reads (40%) | catalogued as rs1555615567, CS072253, CS1512934, COSV62205034; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADAT | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV100528729; called by muse, mutect2
- AAK1 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68644021; called by muse, mutect2, varscan2
- ABCA13 | c.353T>A p.I118K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV70030204; called by muse, mutect2, varscan2
- ABCA13 | c.1471T>C p.F491L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV70026258; called by muse, mutect2, varscan2
- ABCA3 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57054072; called by muse, mutect2, varscan2
- ABCC11 | c.3941C>T p.T1314I | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV62323336; called by muse, mutect2, varscan2
- ABCC2 | c.2008A>G p.I670V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64986418; called by muse, mutect2, varscan2
- ABCC2 | c.3610A>T p.N1204Y | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100966738; called by muse, mutect2
- ABCC5 | c.1990A>G p.R664G | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV55590642; called by muse, mutect2, varscan2
- ABHD13 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65534957; called by muse, mutect2, varscan2
- ABHD2 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV61774228; called by muse, mutect2, varscan2
- ABR | c.2482A>T p.M828L (on ENST00000302538 / NM_021962.5; = p.M791L on NM_001092.5) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV52146045; called by muse, mutect2, varscan2
- AC093155.3 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV63350560; called by muse, mutect2, varscan2
- ACE | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs989791368, COSV52007304; called by muse, mutect2, varscan2
- ACHE | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53817848; called by muse, mutect2, varscan2
- ACOX1 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs752885559, COSV53133469; called by muse, mutect2, varscan2
- ACSF2 | c.1625G>C p.G542A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955789; called by muse, mutect2, varscan2
- ACTN1 | c.2534T>C p.M845T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1436008180, COSV51992471; called by muse, mutect2, varscan2
- ACTN1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs760908092, COSV51992496; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADCY2 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 110/409 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57874545; called by muse, mutect2, varscan2
- ADGRG4 | c.8231C>T p.A2744V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs775547546, COSV54957050; called by muse, mutect2, varscan2
- ADIPOR2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV63946445; called by muse, mutect2, varscan2
- AFDN | c.4688A>G p.E1563G | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1305810725, COSV60045606; called by muse, mutect2, varscan2
- AFDN | c.5260A>T p.T1754S (on ENST00000447894 / NM_001366320.1; = p.T1673S on NM_001207008.1) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV63537449; called by muse, mutect2, varscan2
- AGAP1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779782500, COSV58325426; called by muse, mutect2, varscan2
- AGBL2 | c.637A>G p.K213E | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV54092344; called by muse, mutect2, varscan2
- AGFG2 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV53545272; called by muse, mutect2, varscan2
- AGO1 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV64595396; called by muse, mutect2, varscan2
- AGO2 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV55047860; called by muse, mutect2, varscan2
- AGO3 | c.2507A>T p.N836I | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV99869455; called by muse, mutect2
- AGTR2 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100903633; called by muse, mutect2, varscan2
- AHCTF1 | c.6436T>A p.S2146T (on ENST00000366508; = p.S2120T on NM_015446.5) | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV58250663; called by muse, mutect2, varscan2
- AHNAK | c.14561T>C p.V4854A | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV57214910; called by muse, mutect2, varscan2
- AHNAK | c.10873A>G p.T3625A | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV57214918; called by muse, mutect2, varscan2
- AHNAK2 | c.1976del p.K659Rfs*5 | Frame Shift Del (DEL) | VAF 61/279 reads (22%) | catalogued as rs1178630013; called by mutect2, pindel, varscan2
- AKAP10 | c.1930A>G p.S644G | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs139686167; called by muse, mutect2, varscan2
- AL035461.3 | c.2844C>A p.F948L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as rs749890487, COSV66651882; called by muse, mutect2, varscan2
- ALB | c.1785+2T>C p.X595_splice | Splice Site (SNP) | VAF 38/140 reads (27%) | catalogued as COSV55738487; called by muse, mutect2, varscan2
- ALDH3A2 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778115541, CM980053, COSV51565484; called by muse, mutect2, varscan2
- ALG6 | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 45/178 reads (25%) | catalogued as COSV54763209; called by muse, mutect2, varscan2
- ALOX15 | c.1747T>C p.F583L | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53397901; called by muse, mutect2, varscan2
- AMD1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV64387423; called by muse, mutect2, varscan2
- AMIGO3 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57538730; called by muse, mutect2, varscan2
- AMZ1 | c.601+2T>C p.X201_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56687067; called by mutect2, varscan2
- ANGPTL4 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV100035282; called by muse, mutect2, varscan2
- ANK2 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 50/127 reads (39%) | catalogued as COSV52163049; called by muse, mutect2, varscan2
- ANK3 | c.4217A>T p.Q1406L (on ENST00000280772 / NM_001320874.2; = p.Q540L on NM_001149.3) | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55059966; called by muse, mutect2, varscan2
- ANKRD11 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56361838; called by muse, mutect2, varscan2
- ANKRD26 | c.1635+2T>C p.X545_splice | Splice Site (SNP) | VAF 59/230 reads (26%) | catalogued as COSV101063443; called by muse, mutect2, varscan2
- ANKRD28 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101080968; called by muse, mutect2
- ANKRD45 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60961262; called by muse, mutect2, varscan2
- ANKRD49 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV57060191; called by muse, varscan2
- AOX1 | c.3065C>A p.A1022D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV101022251; called by muse, mutect2
- AP2A2 | c.554T>C p.M185T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV59960541; called by muse, mutect2, varscan2
- AP5B1 | c.2393T>C p.V798A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1042025193, COSV100376170; called by muse, mutect2, varscan2
- API5 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 56/173 reads (32%) | catalogued as COSV66633440; called by muse, mutect2, varscan2
- APOB | c.3988C>A p.L1330M | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); catalogued as COSV51937087, COSV51948460; called by muse, mutect2, varscan2
- APOBEC1 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV57549060; called by muse, mutect2, varscan2
- AR | c.2763A>T p.*921Cext*95 | Nonstop Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV101019620; called by muse, mutect2
- ARHGAP26 | c.661T>A p.F221I | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99191524; called by muse, mutect2, varscan2
- ARHGEF10L | c.191del p.P64Hfs*2 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs943131944; called by mutect2, pindel, varscan2
- ARHGEF11 | c.1805+2T>C p.X602_splice | Splice Site (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100169014; called by muse, mutect2, varscan2
- ARHGEF17 | c.1850dup p.G618Wfs*4 | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | catalogued as rs761146124; called by mutect2, varscan2
- ARHGEF17 | c.4589T>A p.L1530Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55232850; called by muse, mutect2, varscan2
- ARHGEF2 | c.340+2T>C p.X114_splice (on ENST00000361247 / NM_001162383.2; = p.X87_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 17/169 reads (10%) | catalogued as COSV100561225; called by muse, mutect2, varscan2
- ARHGEF9 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs781823638, COSV53638703; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ARID1B | c.3118A>G p.T1040A | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs1463153065, COSV51653097; called by muse, mutect2, varscan2
- ARSL | c.1681A>G p.R561G | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1172349807, COSV66965317; called by muse, mutect2, varscan2
- AS3MT | c.466T>G p.C156G | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV54917074; called by muse, mutect2, varscan2
- ASAP1 | c.1880+2T>C p.X627_splice | Splice Site (SNP) | VAF 29/63 reads (46%) | catalogued as COSV100727938; called by muse, mutect2, varscan2
- ASB1 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV52827107; called by muse, mutect2, varscan2
- ASIC3 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52522718; called by muse, mutect2, varscan2
- ASPM | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99661183; called by muse, mutect2
- ATG13 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56319657; called by muse, varscan2
- ATP2B4 | c.2644A>G p.M882V | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58176576; called by muse, mutect2, varscan2
- ATP5PO | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV51708445; called by muse, mutect2, varscan2
- ATP6AP1 | c.1254T>A p.C418* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | catalogued as COSV63895736; called by muse, mutect2, varscan2
- ATP7A | c.4268G>A p.R1423Q | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as rs368091927, COSV100431768; called by muse, mutect2, varscan2
- ATPSCKMT | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54726590; called by muse, mutect2
- B4GALT1 | c.651G>A p.A217= | Splice Region (SNP) | VAF 14/88 reads (16%) | catalogued as rs373709745, COSV101122964; called by muse, mutect2, varscan2
- BAZ1B | c.2438A>G p.N813S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs1048306515; called by muse, mutect2
- BAZ1B | c.784T>G p.L262V | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV59991489; called by muse, mutect2, varscan2
- BCCIP | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs544090028, COSV52940473; called by muse, mutect2, varscan2
- BCKDHA | c.484+2T>C p.X162_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54197323; called by muse, mutect2, varscan2
- BCL10 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1557784897, COSV65353853; called by muse, mutect2, varscan2
- BCL2A1 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51213238; called by muse, mutect2, varscan2
- BEND6 | c.331T>A p.L111M | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66069078; called by muse, mutect2, varscan2
- BEX2 | c.28A>C p.N10H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV65501046; called by muse, mutect2
- BEX3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55421314; called by muse, mutect2, varscan2
- BIRC6 | c.703A>C p.I235L | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.202); catalogued as COSV101429002; called by muse, mutect2, varscan2
- BNC1 | c.2491G>C p.V831L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV100597506; called by muse, mutect2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | catalogued as rs751941533; called by mutect2, varscan2
- BRAP | c.470T>A p.V157E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV59536829; called by muse, varscan2
- BRWD3 | c.4174A>G p.K1392E | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV64748642; called by muse, mutect2, varscan2
- BTAF1 | c.2684A>G p.N895S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99795876; called by mutect2, varscan2
- BTBD2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99724977; called by muse, mutect2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs752512017; called by mutect2, varscan2
- BUB1 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57063840; called by muse, mutect2, varscan2
- C11orf58 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57178596; called by muse, mutect2, varscan2
- C3 | c.2670dup p.K891Qfs*33 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs750770711; called by mutect2, varscan2
- C7 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.207); catalogued as rs1235918382, COSV57474888; called by muse, mutect2, varscan2
- C9orf135 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65875502; called by muse, mutect2, varscan2
- CACNA1D | c.2369A>G p.K790R (on ENST00000350061 / NM_001128840.3; = p.K810R on NM_000720.4) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs763129695, COSV55448360; called by muse, mutect2, varscan2
- CACNA2D4 | c.1256A>G p.N419S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200395562; called by muse, mutect2, varscan2
- CADM3 | c.1187A>G p.Y396C (on ENST00000368125 / NM_001127173.3; = p.Y430C on NM_021189.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929675; called by muse, mutect2
- CAMSAP2 | c.2131A>G p.T711A (on ENST00000236925 / NM_001297707.2; = p.T700A on NM_203459.3) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52671240; called by muse, mutect2, varscan2
- CAPN1 | c.2079C>A p.D693E | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV54198827, COSV54199386; called by muse, mutect2, varscan2
- CAPN7 | c.1010A>T p.H337L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99513068; called by muse, mutect2
- CAPS | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99222525; called by muse, mutect2
- CARD14 | c.2906G>A p.S969N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV58339321; called by muse, mutect2, varscan2
- CARMIL1 | c.1533A>G p.I511M | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs909240665, COSV61517941; called by muse, mutect2, varscan2
- CASQ1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207492312, COSV63624188; called by muse, mutect2, varscan2
- CATSPER3 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV50946671; called by muse, varscan2
- CCAR2 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51515339; called by muse, mutect2, varscan2
- CCDC112 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101100542; called by muse, mutect2
- CCDC136 | c.2290A>G p.T764A | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99923285; called by muse, mutect2, varscan2
- CCDC158 | c.803+2T>C p.X268_splice | Splice Site (SNP) | VAF 79/206 reads (38%) | catalogued as COSV66356541; called by muse, mutect2, varscan2
- CCDC158 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV66356095; called by muse, mutect2, varscan2
- CCDC191 | c.1916A>C p.N639T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as COSV99878806; called by muse, mutect2
- CCDC61 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.041); catalogued as COSV50516857; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as rs762553129; called by mutect2, varscan2
- CCNT1 | c.2155C>G p.P719A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56064353; called by muse, mutect2, varscan2
- CCT6B | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV58489377; called by muse, mutect2, varscan2
- CD164L2 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV64995695; called by muse, mutect2, varscan2
- CDC23 | c.415+2T>A p.X139_splice | Splice Site (SNP) | VAF 35/127 reads (28%) | catalogued as COSV101203008; called by muse, mutect2, varscan2
- CDH20 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1481050469, COSV53010490; called by muse, mutect2, varscan2
- CEL | c.1558G>T p.G520C (on ENST00000673714; = p.G517C on NM_001807.6) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV60827489; called by mutect2, varscan2
- CELSR1 | c.8191G>A p.A2731T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs775423517, COSV53090963; called by muse, mutect2, varscan2
- CEP350 | c.2141T>A p.M714K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV62603165; called by muse, mutect2, varscan2
- CEP44 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); catalogued as COSV56659401; called by muse, mutect2, varscan2
- CEP72 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99375335; called by muse, mutect2
- CEP95 | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782744733, COSV101616345; called by muse, mutect2
- CFAP251 | c.2344C>A p.L782M | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56610798; called by muse, mutect2, varscan2
- CFAP47 | c.1526T>C p.F509S | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52885057; called by muse, varscan2
- CFAP58 | c.2058G>A p.M686I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63834243; called by muse, mutect2, varscan2
- CFAP74 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54568264; called by muse, mutect2, varscan2
- CGNL1 | c.72T>A p.D24E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99849236; called by muse, mutect2, varscan2
- CHD6 | c.5651T>C p.M1884T | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100951384; called by muse, mutect2
- CHD7 | c.7549A>G p.K2517E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101418480; called by muse, mutect2, varscan2
- CHSY1 | c.1939A>G p.N647D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761334027, COSV54253490; called by muse, mutect2, varscan2
- CIITA | c.3241T>C p.Y1081H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV60857478; called by muse, mutect2, varscan2
- CKAP5 | c.2803A>C p.I935L | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56368169, COSV56374005; called by muse, varscan2
- CLCN3 | c.2296A>G p.T766A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV61627208; called by muse, mutect2, varscan2
- CLK2 | c.714C>A p.H238Q (on ENST00000368361 / NM_001294339.2; = p.H237Q on NM_003993.4) | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56945303; called by muse, mutect2, varscan2
- CNOT8 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53585657; called by muse, mutect2, varscan2
- CNTLN | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 23/163 reads (14%) | catalogued as COSV52080480, COSV99265829; called by muse, varscan2
- CNTLN | c.2762A>T p.Q921L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV99265833; called by muse, mutect2
- CNTN1 | c.1506A>G p.T502= | Splice Region (SNP) | VAF 28/105 reads (27%) | catalogued as COSV61640004; called by muse, mutect2, varscan2
- COG1 | c.2837A>G p.D946G | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1288680572, COSV100245379, COSV55429907; called by muse, mutect2, varscan2
- COX15 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV50012352; called by muse, mutect2, varscan2
- CPAMD8 | c.2211+1G>A p.X737_splice (on ENST00000651564; = p.X690_splice on NM_015692.5) | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as rs374939930; called by muse, mutect2, varscan2
- CPSF7 | c.1343A>G p.H448R (on ENST00000394888 / NM_001136040.4; = p.H491R on NM_024811.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61211191; called by muse, mutect2, varscan2
- CPXM2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.901); catalogued as rs778892334, COSV53856577; called by muse, mutect2, varscan2
- CREBBP | c.4864T>C p.Y1622H | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52125029; called by muse, mutect2, varscan2
- CRLF3 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1331477288, COSV60835949; called by muse, mutect2, varscan2
- CRMP1 | c.1587del p.I531Sfs*16 | Frame Shift Del (DEL) | VAF 82/253 reads (32%) | catalogued as COSV61480425, COSV61480708; called by mutect2, pindel, varscan2
- CRYL1 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53418419; called by muse, mutect2, varscan2
- CSF2RA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs749182596, COSV62624548; called by muse, mutect2, varscan2
- CSMD3 | c.7825G>A p.V2609M (on ENST00000297405 / NM_001363185.1; = p.V2505M on NM_052900.3) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV52191392; called by muse, varscan2
- CSNK1E | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV63291117; called by muse, mutect2, varscan2
- CSTF1 | c.1209A>G p.I403M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as COSV53858891; called by muse, mutect2, varscan2
- CSTF3 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV60609198; called by muse, mutect2, varscan2
- CSTF3 | c.1414A>C p.T472P | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV60611531; called by muse, mutect2, varscan2
- CTCFL | c.1871A>G p.K624R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54777093, COSV99713352; called by muse, mutect2, varscan2
- CUL2 | c.1400A>T p.Y467F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV66079325; called by muse, mutect2, varscan2
- CUL7 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54817464; called by muse, mutect2, varscan2
- CXCR4 | c.432T>A p.S144R | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54012823; called by muse, mutect2, varscan2
- CYBC1 | c.233T>G p.V78G | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV60064225; called by muse, mutect2, varscan2
- CYLC1 | c.971del p.K324Rfs*3 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as COSV61413505; called by mutect2, pindel, varscan2
- CYP26B1 | c.528del p.E177Rfs*12 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV50013503; called by mutect2, pindel, varscan2
- CYP2S1 | c.874A>G p.M292V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1229913643, COSV59506220; called by muse, mutect2, varscan2
- CYP39A1 | c.932-2A>G p.X311_splice | Splice Site (SNP) | VAF 51/131 reads (39%) | catalogued as COSV51496055; called by muse, mutect2, varscan2
- DAAM1 | c.503T>C p.M168T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV62836601; called by muse, mutect2, varscan2
- DAPK1 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV63787666; called by muse, mutect2, varscan2
- DCDC1 | c.3304G>A p.V1102I (on ENST00000597505 / NM_001367979.1; = p.V209I on NM_020869.3) | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs138977837; called by muse, mutect2, varscan2
- DCTN2 | c.1124A>G p.Q375R (on ENST00000548249 / NM_001261413.2; = p.Q380R on NM_006400.4) | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63074661; called by muse, mutect2, varscan2
- DDHD2 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs776283403, COSV68157942; called by muse, mutect2, varscan2
- DDX58 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV65883351; called by muse, mutect2, varscan2
- DELE1 | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV52005024; called by muse, mutect2, varscan2
- DENND4B | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218010520, COSV63409417; called by muse, mutect2, varscan2
- DGKE | c.1490A>T p.N497I | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV52349926; called by muse, mutect2, varscan2
- DGKK | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV65707624; called by muse, mutect2, varscan2
- DHRS7B | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100683993, COSV60887907; called by muse, mutect2, varscan2
- DIP2C | c.3047T>C p.V1016A | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771896590, COSV55159584; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLC1 | c.2146A>T p.I716F (on ENST00000276297 / NM_001348081.2; = p.I279F on NM_006094.5) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52306125; called by muse, mutect2, varscan2
- DMD | c.10577G>A p.R3526H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs139547504, COSV58890311; ClinVar: benign; called by muse, mutect2, varscan2
- DMD | c.9211C>G p.P3071A | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58912902; called by muse, mutect2, varscan2
- DMRTC2 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.715); catalogued as rs373577927; called by muse, mutect2, varscan2
- DNAH12 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV60857143; called by muse, mutect2, varscan2
- DNAH2 | c.5111T>C p.I1704T | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV66720048; called by muse, mutect2, varscan2
- DNAH8 | c.10326del p.L3443Yfs*17 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | catalogued as rs1173391371, COSV100545327; called by mutect2, pindel, varscan2
- DNAI3 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99642452; called by muse, mutect2, varscan2
- DNAJA4 | c.877+2T>C p.X293_splice (on ENST00000343789; = p.X322_splice on NM_018602.3) | Splice Site (SNP) | VAF 113/196 reads (58%) | catalogued as COSV59425716; called by muse, mutect2, varscan2
- DNAJC5B | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.364); catalogued as COSV52537611; called by muse, mutect2, varscan2
- DNM1 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100360402; called by muse, mutect2, varscan2
- DNTTIP2 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63284071; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 20/179 reads (11%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK8 | c.5329A>G p.R1777G | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV66620398; called by muse, mutect2, varscan2
- DOLPP1 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV59910434; called by muse, mutect2, varscan2
- DPEP3 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52051444; called by muse, mutect2, varscan2
- DPP6 | c.1159A>G p.K387E (on ENST00000377770 / NM_001364500.2; = p.K325E on NM_001936.5) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59615431; called by muse, mutect2, varscan2
- DPP8 | c.1005T>C p.G335= (on ENST00000341861 / NM_001320875.2; = p.G319= on NM_017743.6) | Splice Region (SNP) | VAF 57/110 reads (52%) | catalogued as COSV55679048; called by muse, mutect2, varscan2
- DRC1 | c.1715T>C p.M572T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs777089934, COSV55503890; called by muse, mutect2, varscan2
- DRD1 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67104684; called by muse, mutect2, varscan2
- DSTYK | c.2341A>G p.K781E | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV65686636; called by muse, mutect2, varscan2
- DUSP7 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56589105; called by muse, mutect2, varscan2
- DYNC1H1 | c.12490A>G p.I4164V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV64137366; called by muse, mutect2, varscan2
- DYNC1H1 | c.13595A>G p.N4532S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV100795365, COSV64137371; called by muse, mutect2, varscan2
- DYNC2H1 | c.4719A>T p.Q1573H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62094988; called by muse, mutect2, varscan2
- DYSF | c.4638G>A p.K1546= | Splice Region (SNP) | VAF 22/89 reads (25%) | catalogued as COSV50369369; called by muse, mutect2, varscan2
- DZIP3 | c.1963G>C p.V655L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as COSV64312192; called by muse, mutect2, varscan2
- E2F7 | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.255); catalogued as COSV59740306; called by muse, mutect2, varscan2
- E2F8 | c.2442A>C p.K814N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV51463691; called by muse, mutect2, varscan2
- EAF1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67542154; called by muse, mutect2, varscan2
- EAPP | c.75-1G>A p.X25_splice | Splice Site (SNP) | VAF 31/139 reads (22%) | catalogued as COSV51651907; called by muse, mutect2
- EEF1A1 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV58549749; called by muse, mutect2, varscan2
- EGFL6 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV63633991; called by muse, mutect2, varscan2
- EGR1 | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53519619; called by muse, mutect2, varscan2
- EIF3G | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs1396801898, COSV53458633; called by muse, mutect2, varscan2
- EIF5B | c.1951-2A>G p.X651_splice | Splice Site (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99178902; called by muse, mutect2, varscan2
- ELK1 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV55953012; called by muse, mutect2, varscan2
- ELOVL5 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV58650757; called by muse, mutect2, varscan2
- EMC2 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV55209324; called by muse, mutect2, varscan2
- EMC3 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99794088; called by muse, mutect2
- EMILIN3 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1046777310, COSV60036494; called by muse, mutect2, varscan2
- ENPP1 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs750660271, COSV62932576; called by muse, mutect2, varscan2
- ENPP5 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100040654; called by muse, mutect2
- EP300 | c.4608A>T p.E1536D | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV54333476; called by muse, mutect2, varscan2
- EPC2 | c.285A>T p.K95N | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51544384; called by muse, mutect2, varscan2
- EPG5 | c.7601T>C p.V2534A | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56350361; called by muse, mutect2, varscan2
- EPHB2 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65862801; called by muse, mutect2, varscan2
- EPS15 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65542586; called by muse, mutect2, varscan2
- ERBB4 | c.3065A>G p.Y1022C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61490760; called by muse, mutect2, varscan2
- ERCC6 | c.4062G>T p.Q1354H | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV63390398; called by muse, mutect2, varscan2
- ETV7 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60317103; called by muse, mutect2, varscan2
- EXPH5 | c.5900A>T p.D1967V | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99762256; called by muse, mutect2, varscan2
- EXT1 | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65479885; called by muse, varscan2
- EXT1 | c.233T>A p.V78E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV65479890; called by muse, varscan2
- EXT2 | c.1462G>A p.V488I (on ENST00000343631; = p.V521I on NM_000401.3) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.62); catalogued as rs139153420; called by muse, mutect2, varscan2
- F11 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374606272; called by muse, mutect2, varscan2
- F8 | c.5813A>G p.H1938R | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as CM083809, CM105304, COSV64269827, COSV64273874; called by muse, mutect2, varscan2
- FAM131A | c.308A>G p.E103G (on ENST00000310585; = p.E134G on NM_144635.5) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55601384; called by muse, mutect2, varscan2
- FAM13B | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as COSV50366769; called by muse, mutect2, varscan2
- FAM13C | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV53249072; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM166A | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100458243; called by muse, mutect2
- FAM184A | c.3335T>A p.F1112Y | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs186112489, COSV58854721; called by muse, mutect2, varscan2
- FAM193A | c.3754T>C p.W1252R (on ENST00000324666 / NM_001256666.1; = p.W1211R on NM_003704.3) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61194377; called by muse, mutect2, varscan2
- FAM193B | c.1180A>C p.S394R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61557830; called by muse, mutect2, varscan2
- FAM47B | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.66); catalogued as rs1238155640, COSV61454127; called by muse, mutect2, varscan2
- FAM91A1 | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58237311; called by muse, mutect2, varscan2
- FAM98A | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV53210383; called by muse, mutect2, varscan2
- FANCD2 | c.2610G>T p.R870S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as COSV55038520; called by muse, mutect2, varscan2
- FARP2 | c.599T>A p.I200K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50871703; called by muse, mutect2, varscan2
- FARSB | c.350T>A p.I117K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1360528744, COSV56049811; called by muse, mutect2, varscan2
- FAT1 | c.12034A>G p.T4012A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756524012, COSV101499660; called by muse, mutect2, varscan2
- FAT2 | c.10606A>C p.I3536L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV55820457; called by muse, mutect2, varscan2
- FAT3 | c.5045A>G p.E1682G | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53101082, COSV53116642; called by muse, mutect2, varscan2
- FBLN1 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53045095; called by muse, mutect2
- FBXL13 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100501589; called by muse, mutect2
- FBXL6 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310763551, COSV100096099; called by muse, mutect2
- FBXO11 | c.1822G>T p.E608* (on ENST00000403359 / NM_001190274.2; = p.E524* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV57019999; called by muse, mutect2, varscan2
- FBXO24 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV53826346; called by muse, mutect2, varscan2
- FBXW7 | c.529G>A p.E177K (on ENST00000281708 / NM_001349798.2; = p.E97K on NM_018315.5) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV55893252, COSV55918989, COSV55933936; called by muse, mutect2, varscan2
- FGD6 | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs1223034061, COSV59693603; called by muse, mutect2, varscan2
- FGFR1 | c.310A>C p.S104R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.038); catalogued as COSV58335211; called by muse, mutect2, varscan2
- FGG | c.124-2A>G p.X42_splice | Splice Site (SNP) | VAF 54/154 reads (35%) | catalogued as COSV60195486; called by muse, mutect2, varscan2
- FIG4 | c.2458A>G p.R820G | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV57787856; called by muse, varscan2
- FKBP2 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58587969; called by muse, mutect2, varscan2
- FKBPL | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as COSV64322503; called by muse, mutect2, varscan2
- FNDC7 | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99601783; called by muse, mutect2
- FOCAD | c.5354T>G p.V1785G | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1486730682, COSV100620724; called by muse, mutect2
- FOXM1 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1235550561, COSV61206133, COSV61206184; called by muse, mutect2, varscan2
- FRMD5 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs907802743, COSV68722159; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSHB | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569531; called by muse, mutect2, varscan2
- FSIP1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63225015; called by muse, mutect2, varscan2
- FTSJ3 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63789264; called by muse, mutect2, varscan2
- FZD1 | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV55310793; called by muse, mutect2, varscan2
- GALNTL5 | c.153del p.V52Cfs*17 | Frame Shift Del (DEL) | VAF 37/93 reads (40%) | catalogued as rs746301883; called by mutect2, pindel, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | catalogued as rs758551787; called by mutect2, varscan2
- GBA2 | c.2495T>C p.M832T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62305873; called by muse, mutect2, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs777909420; called by mutect2, pindel, varscan2
- GDF9 | c.576A>T p.R192S | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV51526409; called by muse, mutect2, varscan2
- GDF9 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.872); catalogued as rs1254962303, COSV51526418; called by muse, mutect2, varscan2
- GDPD5 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61127798; called by muse, mutect2, varscan2
- GEMIN8 | c.474G>A p.R158= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs1459952949, COSV60550672; called by muse, mutect2, varscan2
- GFRAL | c.1087T>C p.C363R | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV61231291; called by muse, mutect2, varscan2
- GIGYF1 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1404908325, COSV51942156; called by muse, mutect2, varscan2
- GIN1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101204423; called by muse, mutect2
- GMEB2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as rs1311675136, COSV56607276; called by muse, mutect2, varscan2
- GNL2 | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56170039; called by muse, mutect2, varscan2
- GOLGA4 | c.2762A>G p.K921R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV62710927; called by muse, mutect2, varscan2
- GOLGA8A | c.1657G>T p.A553S (on ENST00000432566; = p.A525S on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62169846; called by mutect2, varscan2
- GORASP1 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56532170; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 70/192 reads (36%) | catalogued as rs370114090; called by mutect2, varscan2
- GOT1L1 | c.55A>T p.S19C | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV100294736; called by muse, mutect2
- GPR15 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755430790, COSV52520634; called by muse, mutect2, varscan2
- GPR171 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs766785001, COSV99854878; called by muse, mutect2, varscan2
- GPSM2 | c.1815+2T>C p.X605_splice | Splice Site (SNP) | VAF 25/104 reads (24%) | catalogued as COSV51442745; called by muse, mutect2, varscan2
- GRHL2 | c.1698G>A p.A566= | Splice Region (SNP) | VAF 26/229 reads (11%) | catalogued as COSV52548884, COSV99306889; called by muse, mutect2, varscan2
- GRXCR1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as COSV67669920; called by muse, mutect2, varscan2
- GTF2H3 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV57458999; called by muse, mutect2, varscan2
- GTF2I | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV60401462; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs1175807341, COSV63100385; called by mutect2, varscan2
- GTPBP3 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.685); catalogued as COSV50178893; called by muse, mutect2, varscan2
- GZF1 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57636236; called by muse, mutect2, varscan2
- HAUS7 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100444339; called by muse, mutect2
- HCAR3 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100811815; called by muse, mutect2
- HEATR1 | c.6371A>G p.Q2124R | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV59381685; called by muse, mutect2, varscan2
- HEATR5B | c.1901T>A p.I634N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV51853169; called by muse, varscan2
- HELZ | c.5701C>T p.R1901W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs201212218; called by muse, mutect2, varscan2
- HGS | c.1765T>G p.F589V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV61268072; called by muse, varscan2
- HIVEP2 | c.6061T>C p.C2021R | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV50014646; called by muse, mutect2, varscan2
- HMBOX1 | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55068454; called by muse, mutect2, varscan2
- HMCN1 | c.2476T>C p.W826R | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54903171; called by muse, varscan2
- HMCN2 | c.2329A>T p.I777F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV70280061; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs761272507; called by mutect2, varscan2
- HPF1 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV66422055; called by muse, mutect2, varscan2
- HSD3B7 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52680633; called by muse, varscan2
- HSPA12A | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs199760082; called by muse, mutect2, varscan2
- HSPG2 | c.10723T>C p.L3575= | Splice Region (SNP) | VAF 21/51 reads (41%) | catalogued as COSV65933235; called by muse, mutect2, varscan2
- HUWE1 | c.1116T>C p.D372= | Splice Region (SNP) | VAF 24/133 reads (18%) | catalogued as COSV53346935; called by muse, mutect2, varscan2
- ID1 | c.427-2A>G p.X143_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as rs532455191, COSV101076851; called by muse, mutect2, varscan2
- IDH3A | c.263T>C p.M88T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs1338121896, COSV55112955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFFO1 | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60737715; called by muse, mutect2, varscan2
- IFNA7 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 70/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497616; called by muse, mutect2, varscan2
- IFNL1 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV61317812; called by muse, mutect2, varscan2
- IGDCC4 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61536970; called by muse, mutect2, varscan2
- IKZF5 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV64397583; called by muse, mutect2, varscan2
- IL1RAP | c.464T>A p.I155N | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50762072; called by muse, mutect2, varscan2
- IL2RG | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52148538; called by muse, mutect2, varscan2
- ILF3 | c.2626T>C p.S876P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.094); catalogued as COSV99140328; called by mutect2, varscan2
- INO80D | c.1615A>T p.K539* | Nonsense Mutation (SNP) | VAF 22/240 reads (9%) | catalogued as COSV101305893; called by muse, mutect2
- INTS1 | c.2951T>C p.V984A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.076); catalogued as COSV67177674; called by muse, mutect2, varscan2
- INTS11 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV59672385; called by muse, mutect2, varscan2
- INTS2 | c.1731T>G p.I577M | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52153369; called by muse, mutect2, varscan2
- INTS6 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV60878255; called by muse, mutect2, varscan2
- INTS8 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as COSV58250625; called by muse, mutect2, varscan2
- INTS8 | c.2791T>C p.Y931H | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV57376184; called by muse, mutect2, varscan2
- IRF5 | c.398dup p.E134* | Frame Shift Ins (INS) | VAF 29/183 reads (16%) | catalogued as rs1418546998; called by mutect2, pindel, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 54/174 reads (31%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGAL | c.2146-2A>G p.X716_splice | Splice Site (SNP) | VAF 18/136 reads (13%) | catalogued as COSV100776363; called by muse, mutect2, varscan2
- ITGB5 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99951105; called by muse, mutect2, varscan2
- ITGB8 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56009252; called by muse, mutect2, varscan2
- ITIH6 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs750178200, COSV54489596; called by muse, mutect2, varscan2
- ITPR2 | c.5021T>A p.I1674N | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67269866; called by muse, mutect2, varscan2
- ITSN2 | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.124); catalogued as COSV61947827; called by muse, mutect2, varscan2
- JAK2 | c.2572-2A>G p.X858_splice | Splice Site (SNP) | VAF 18/310 reads (6%) | catalogued as COSV101079902; called by muse, mutect2
- JRKL | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs781678964, COSV53593588; called by muse, mutect2, varscan2
- KAT14 | c.2086T>C p.Y696H | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66607821; called by muse, mutect2, varscan2
- KAT2A | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52426025; called by muse, mutect2, varscan2
- KATNA1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 98/181 reads (54%) | catalogued as rs372912527; called by muse, mutect2, varscan2
- KATNIP | c.4559T>C p.V1520A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55181440; called by muse, mutect2, varscan2
- KBTBD6 | c.1945T>A p.F649I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV65271363; called by muse, mutect2, varscan2
- KBTBD7 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV65266453; called by muse, mutect2
- KCNH3 | c.2042G>A p.S681N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57790955; called by muse, mutect2, varscan2
- KCNJ9 | c.583T>A p.L195M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV63631849; called by muse, varscan2
- KCNMA1 | c.3335A>G p.D1112G (on ENST00000286628 / NM_001161352.2; = p.D1054G on NM_002247.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54250720; called by muse, mutect2, varscan2
- KCNMA1 | c.2832C>G p.I944M (on ENST00000286628 / NM_001161352.2; = p.I886M on NM_002247.4) | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54229234; called by muse, mutect2, varscan2
- KCNQ2 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV60434451; called by muse, varscan2
- KCNQ4 | c.710A>G p.E237G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61273298; called by muse, mutect2, varscan2
- KCNT1 | c.1622A>G p.E541G (on ENST00000488444; = p.E560G on NM_020822.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53702067; called by muse, mutect2, varscan2
- KCTD10 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57327027; called by muse, mutect2, varscan2
- KHDC4 | c.1743T>A p.H581Q | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100851026; called by muse, mutect2, varscan2
- KIAA1191 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53798968; called by muse, mutect2, varscan2
- KIF12 | c.635T>A p.L212H (on ENST00000640217; = p.L74H on NM_138424.1) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936302; called by muse, mutect2
- KIF13A | c.3061T>C p.F1021L | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99438318; called by muse, mutect2, varscan2
- KIF14 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV66261884; called by muse, mutect2, varscan2
- KIF20B | c.1862+2T>C p.X621_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53308053; called by muse, mutect2
- KIF24 | c.3235A>C p.S1079R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52659092; called by muse, mutect2, varscan2
- KIF26B | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV69463224; called by muse, mutect2, varscan2
- KIF4A | c.1923+2T>C p.X641_splice | Splice Site (SNP) | VAF 11/113 reads (10%) | catalogued as COSV100979656; called by muse, mutect2, varscan2
- KIFC3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1361169981, COSV65550499; called by muse, mutect2, varscan2
- KISS1 | c.64T>A p.L22I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.294); catalogued as COSV65816982; called by muse, mutect2, varscan2
- KLHL13 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV53247976, COSV99450856; called by muse, mutect2, varscan2
- KLHL14 | c.1236A>G p.E412= | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV63832686; called by muse, mutect2, varscan2
- KLHL4 | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV64142851; called by muse, mutect2, varscan2
- KMT2A | c.5515A>G p.T1839A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV63286143; called by muse, mutect2, varscan2
- KPNA2 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57857645; called by muse, mutect2, varscan2
- KRTAP13-4 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61879331; called by muse, mutect2, varscan2
- LAMA2 | c.3839C>A p.T1280K | Missense Mutation (SNP) | VAF 100/170 reads (59%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.516); catalogued as COSV70348078; called by muse, mutect2, varscan2
- LAMA2 | c.4846A>G p.T1616A | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101370875; called by muse, mutect2, varscan2
- LAMA5 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1240082287, COSV53360811; called by muse, mutect2, varscan2
- LAMB2 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59733859; called by muse, mutect2, varscan2
- LBR | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55288399, COSV55289106; called by muse, mutect2, varscan2
- LCA5 | c.77del p.D26Vfs*85 | Frame Shift Del (DEL) | VAF 58/369 reads (16%) | catalogued as COSV63971520; called by mutect2, pindel, varscan2
- LILRA2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV52192179, COSV52196813; called by muse, mutect2, varscan2
- LNPK | c.812+2T>C p.X271_splice | Splice Site (SNP) | VAF 24/145 reads (17%) | catalogued as COSV99770507; called by muse, mutect2, varscan2
- LPCAT1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV52042613; called by muse, mutect2, varscan2
- LPCAT2 | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100045366, COSV100045506; called by muse, mutect2
- LPP | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57092960; called by muse, mutect2, varscan2
- LRP2 | c.10651C>T p.R3551C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188450012, COSV55567967; called by muse, mutect2
- LRP5 | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV53716245; called by muse, mutect2, varscan2
- LRR1 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.276); catalogued as COSV53563681; called by muse, mutect2, varscan2
- LRRC27 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV59809082; called by muse, mutect2, varscan2
- LRRK1 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52613074, COSV52625765; called by muse, mutect2, varscan2
- LRRK2 | c.4915dup p.R1639Kfs*13 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | catalogued as rs756089224; called by mutect2, varscan2
- LSMEM2 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs372954818, COSV100269823; called by muse, mutect2, varscan2
- LTBP2 | c.3664T>C p.C1222R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001007; called by muse, mutect2, varscan2
- LTN1 | c.1334T>G p.V445G | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV63733910; called by muse, mutect2, varscan2
- LY75 | c.2410T>C p.Y804H | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55106195; called by muse, mutect2, varscan2
- LYST | c.8332C>G p.R2778G | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV67702767, COSV67707366; called by muse, mutect2, varscan2
- MAD2L1 | c.272T>A p.I91N | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV56636977; called by muse, mutect2, varscan2
- MAGI1 | c.4133T>A p.L1378Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.295); catalogued as COSV58327914; called by muse, mutect2, varscan2
- MAN2B1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55472202; called by muse, mutect2, varscan2
- MAN2B2 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53453291; called by muse, mutect2, varscan2
- MAP10 | c.2111A>G p.Y704C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs928815546, COSV69363719; called by muse, mutect2, varscan2
- MAP2K1 | c.256T>G p.S86A | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV61070954; called by muse, mutect2, varscan2
- MAP3K14 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60923697; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs761388884; called by mutect2, varscan2
- MAPK8IP2 | c.1843T>C p.F615L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50498274; called by muse, mutect2, varscan2
- MBD3 | c.335T>A p.V112E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99337099; called by muse, mutect2, varscan2
- MCF2 | c.2112A>G p.I704M | Missense Mutation (SNP) | VAF 16/315 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100645212; called by muse, mutect2
- MCM10 | c.1345A>C p.S449R (on ENST00000484800 / NM_182751.3; = p.S448R on NM_018518.5) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV101098482; called by muse, varscan2
- MCPH1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60913936; called by muse, mutect2, varscan2
- MED4 | c.357A>C p.Q119H | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1259516991, COSV51639370; called by muse, varscan2
- MED4 | c.265A>C p.I89L | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV51639388; called by muse, varscan2
- MELTF | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV56381682; called by muse, mutect2, varscan2
- MFHAS1 | c.2573T>A p.V858E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV52282540; called by muse, mutect2, varscan2
- MFN2 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373368672; called by mutect2, varscan2
- MIA2 | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs144750088; called by muse, mutect2, varscan2
- MICAL3 | c.1432T>C p.F478L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV99263011; called by muse, mutect2
- MIDN | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV99960432; called by muse, mutect2
- MINDY2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 80/144 reads (56%) | catalogued as COSV57506918; called by muse, mutect2, varscan2
- MINDY3 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV53220703; called by muse, mutect2, varscan2
- MLEC | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.242); catalogued as COSV57329704; called by muse, mutect2, varscan2
- MLH1 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779005, CM101374, COSV51618470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLH3 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53135141; called by muse, mutect2, varscan2
- MMRN1 | c.21T>G p.F7L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV53337783; called by muse, mutect2, varscan2
- MPDZ | c.1205C>A p.P402H | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59942586; called by muse, mutect2, varscan2
- MPRIP | c.1298T>A p.I433N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59048649; called by muse, mutect2, varscan2
- MRPL19 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100718791; called by muse, mutect2
- MRPS26 | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55661723; called by muse, mutect2, varscan2
- MTMR14 | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56005085, COSV56006024; called by muse, mutect2, varscan2
- MTMR3 | c.2074A>G p.I692V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV60304734; called by muse, mutect2, varscan2
- MUC16 | c.20587A>G p.T6863A | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV67468912; called by muse, mutect2, varscan2
- MUC16 | c.9625A>G p.M3209V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs1396654430, COSV67468918; called by muse, mutect2, varscan2
- MUC16 | c.8544A>G p.I2848M | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV67468920; called by muse, mutect2, varscan2
- MYH9 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383986403, COSV53386824; ClinVar: not provided; called by muse, mutect2, varscan2
- MYMK | c.526T>A p.Y176N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60600830; called by muse, mutect2, varscan2
- MYNN | c.1395T>A p.H465Q | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62991370; called by muse, mutect2, varscan2
- MYO9A | c.6257T>C p.I2086T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757005328, COSV61851590; called by muse, mutect2, varscan2
- MYO9A | c.6118T>C p.C2040R | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61851598; called by muse, mutect2, varscan2
- MYOM3 | c.3413T>C p.L1138P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58394643; called by muse, mutect2, varscan2
- MYOT | c.897A>G p.I299M | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV53514931; called by muse, mutect2, varscan2
- N4BP2 | c.1880T>C p.L627S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99789322; called by muse, mutect2, varscan2
- N4BP2L2 | c.1117T>C p.W373R | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57228530; called by muse, mutect2, varscan2
- NAA15 | c.659T>A p.I220N | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56719859; called by muse, mutect2, varscan2
- NAALAD2 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV58958347; called by muse, mutect2, varscan2
- NAALADL1 | c.1599+2T>C p.X533_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as rs1008153681, COSV100368263; called by muse, mutect2, varscan2
- NAALADL2 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.138); catalogued as COSV70295802; called by muse, mutect2, varscan2
- NAT9 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV52853396; called by muse, mutect2, varscan2
- NBEAL1 | c.5594T>A p.L1865H | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV71374438; called by muse, mutect2, varscan2
- NCAN | c.1802A>C p.D601A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99388401; called by muse, mutect2, varscan2
- NCBP1 | c.225-2A>G p.X75_splice | Splice Site (SNP) | VAF 10/140 reads (7%) | catalogued as COSV100912694; called by muse, mutect2
- NCOA1 | c.3938A>G p.N1313S | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV56044814; called by muse, mutect2, varscan2
- NDUFB10 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51910087; called by muse, mutect2, varscan2
- NEB | c.11716C>T p.R3906W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368167657; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NES | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV63961202; called by muse, mutect2, varscan2
- NETO2 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV57453110; called by muse, mutect2, varscan2
- NEURL2 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510162; called by muse, mutect2
- NFE2L1 | c.524T>A p.I175N | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV62583262; called by muse, mutect2, varscan2
- NFKBIZ | c.1621C>G p.Q541E | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV100397221, COSV100397255; called by muse, mutect2
- NGEF | c.1367A>C p.E456A | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.887); catalogued as COSV99891013; called by muse, mutect2, varscan2
- NGEF | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV50923587; called by muse, mutect2, varscan2
- NHS | c.4406A>G p.N1469S | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66275378; called by muse, mutect2, varscan2
- NID2 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53496891, COSV53504093; called by muse, mutect2, varscan2
- NLGN2 | c.1583T>A p.V528D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV57210360; called by muse, mutect2, varscan2
- NLRC5 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52655939; called by muse, mutect2, varscan2
- NLRP14 | c.382A>G p.N128D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1207774716, COSV100205459; called by muse, mutect2, varscan2
- NLRP5 | c.501del p.V168Cfs*72 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | catalogued as COSV101173672; called by mutect2, pindel, varscan2
- NOB1 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV99264097; called by muse, mutect2, varscan2
- NPLOC4 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58616368; called by muse, mutect2, varscan2
- NR2F2 | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67683516; called by muse, mutect2, varscan2
- NR4A2 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59893974; called by muse, mutect2, varscan2
- NRK | c.890del p.N297Ifs*20 | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | catalogued as rs1321315147; called by mutect2, pindel, varscan2
- NSD1 | c.6364T>G p.F2122V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD052495, COSV61776785; called by muse, varscan2
- NSD1 | c.6440T>G p.L2147R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61776793; called by muse, varscan2
- NUP133 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54571815; called by muse, mutect2, varscan2
- NUP155 | c.2751T>A p.C917* (on ENST00000231498 / NM_153485.3; = p.C858* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 23/284 reads (8%) | catalogued as COSV99195269; called by muse, mutect2
- NUP188 | c.4505T>C p.L1502S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV100999409; called by muse, mutect2
- NUP214 | c.4487C>T p.A1496V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV63909917; called by muse, mutect2, varscan2
- OBSCN | c.17912T>C p.V5971A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99484712; called by muse, mutect2, varscan2
- OLA1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375033952, COSV52969227; called by mutect2, varscan2
- OLFM1 | c.1040A>G p.Y347C (on ENST00000371793 / NM_001282611.2; = p.Y329C on NM_014279.5) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53278689; called by muse, mutect2, varscan2
- OR2AG1 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56626183; called by muse, mutect2, varscan2
- OR2B2 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57579777, COSV57580340; called by muse, mutect2, varscan2
- OR4A15 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV59035469; called by muse, mutect2, varscan2
- OR4C6 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as rs1417508824; called by muse, mutect2
- OR5K3 | c.397C>G p.H133D | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV67350143, COSV67350780; called by muse, mutect2, varscan2
- ORAI1 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV57491516; called by muse, varscan2
- OSBPL11 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752911170, COSV56174182; called by muse, mutect2, varscan2
- OTOF | c.3325A>G p.N1109D (on ENST00000272371 / NM_194248.3; = p.N362D on NM_004802.4) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55503905; called by muse, mutect2, varscan2
- OTUD5 | c.1074+2T>C p.X358_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99332274; called by muse, mutect2
- OTUD7A | c.1571T>C p.L524P (on ENST00000307050 / NM_001382637.1; = p.L517P on NM_130901.3) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61039180; called by muse, mutect2, varscan2
- OTUD7B | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64916287; called by muse, mutect2, varscan2
- P2RX3 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs376233059; called by muse, mutect2, varscan2
- PADI2 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64945936; called by muse, mutect2, varscan2
- PARP1 | c.1159+2T>C p.X387_splice | Splice Site (SNP) | VAF 7/76 reads (9%) | catalogued as COSV64691565; called by muse, mutect2
- PBXIP1 | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63777233; called by muse, mutect2
- PCDHA10 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV56505505; called by muse, mutect2, varscan2
- PCDHA7 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV65342449, COSV65344397; called by muse, mutect2, varscan2
- PCDHB6 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781924526, COSV50699470; called by muse, mutect2, varscan2
- PCDHGB3 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV53893385; called by muse, mutect2
- PCDHGC5 | c.979C>G p.Q327E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as COSV52753205; called by mutect2, varscan2
- PCSK2 | c.1484A>C p.E495A | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV52733389; called by muse, mutect2, varscan2
- PDCD7 | c.953T>A p.I318N | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52600537; called by muse, mutect2, varscan2
- PDIK1L | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65322617; called by muse, mutect2, varscan2
- PDRG1 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV52431549; called by muse, mutect2, varscan2
- PDYN | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165004223, COSV54101926; called by muse, mutect2, varscan2
- PEG3 | c.2438T>C p.I813T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV55634889; called by muse, mutect2, varscan2
- PELP1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as COSV52588246; called by muse, mutect2, varscan2
- PER1 | c.1960T>C p.S654P | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); catalogued as COSV100424875; called by mutect2, varscan2
- PEX6 | c.1927A>C p.S643R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV55103350; called by muse, mutect2, varscan2
- PFKFB2 | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | PolyPhen probably damaging (0.973); catalogued as COSV65548165; called by muse, mutect2, varscan2
- PHLDB2 | c.3134C>T p.A1045V (on ENST00000393925 / NM_001134439.2; = p.A1002V on NM_145753.2) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67311518; called by muse, mutect2, varscan2
- PIH1D2 | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54775543; called by muse, mutect2, varscan2
- PIK3R1 | c.1930G>T p.G644C (on ENST00000521381 / NM_181523.3; = p.G374C on NM_181504.4) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57130919, COSV57140018; called by muse, mutect2, varscan2
- PIK3R1 | c.2007T>A p.H669Q (on ENST00000521381 / NM_181523.3; = p.H399Q on NM_181504.4) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57130934; called by muse, mutect2, varscan2
- PIK3R4 | c.1567A>C p.N523H | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63240991; called by muse, mutect2, varscan2
- PIKFYVE | c.4611+2T>C p.X1537_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as COSV52241781; called by muse, mutect2, varscan2
- PINK1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58631265; called by muse, mutect2, varscan2
- PITPNM2 | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54901336; called by muse, mutect2, varscan2
- PITX2 | c.352A>G p.I118V (on ENST00000354925 / NM_001204397.1; = p.I125V on NM_000325.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60741027; called by muse, mutect2, varscan2
- PIWIL2 | c.2543T>C p.V848A | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV63251714; called by muse, mutect2, varscan2
- PKD1L1 | c.3016A>G p.R1006G | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV56966181; called by muse, mutect2, varscan2
- PKHD1 | c.9998+2T>C p.X3333_splice | Splice Site (SNP) | VAF 36/253 reads (14%) | catalogued as COSV100584694; called by muse, varscan2
- PKMYT1 | c.568T>C p.C190R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51891562; called by muse, mutect2, varscan2
- PLAA | c.1475A>G p.D492G | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1439256889, COSV68304952; called by muse, mutect2, varscan2
- PLCL2 | c.3366C>G p.N1122K (on ENST00000615277 / NM_001144382.2; = p.N996K on NM_015184.5) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.039); catalogued as COSV69055533; called by muse, mutect2, varscan2
- PLCXD2 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67340198; called by muse, mutect2, varscan2
- PLEKHG2 | c.3652G>T p.G1218* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV52684050; called by muse, mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs746342377, COSV56183473; called by mutect2, pindel
- PMFBP1 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV52824772; called by muse, mutect2, varscan2
- POLG | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs1060500775, COSV51521816; ClinVar: uncertain significance; called by muse, mutect2
- POLH | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64779632; called by muse, mutect2, varscan2
- POLQ | c.987A>T p.L329F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51752785; called by muse, mutect2, varscan2
- POLR3A | c.1964T>G p.L655R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100965810; called by muse, mutect2, varscan2
- POLR3B | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943889; called by muse, mutect2, varscan2
- POM121 | c.3749A>G p.*1250Wext*? (on ENST00000434423; = p.*985Wext*21 on NM_172020.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 43/155 reads (28%) | catalogued as COSV57516482; called by muse, mutect2, varscan2
- POM121C | c.2930_2931del p.S977Cfs*173 (on ENST00000607367; = p.S735Cfs*173 on NM_001099415.3) | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs782709838; called by pindel, varscan2
- PPEF1 | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV62995795; called by muse, mutect2, varscan2
- PPFIA3 | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV61951971; called by muse, mutect2, varscan2
- PPP1R12B | c.921+2T>C p.X307_splice | Splice Site (SNP) | VAF 33/185 reads (18%) | catalogued as COSV61117609; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 20/114 reads (18%) | catalogued as rs768056539; called by mutect2, varscan2
- PPRC1 | c.4393T>C p.W1465R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.402); catalogued as COSV99532156; called by muse, mutect2
- PRKCI | c.1745T>G p.F582C | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856185; called by muse, mutect2
- PRKDC | c.9932A>G p.N3311S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV58053197; called by muse, mutect2, varscan2
- PRKG1 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64793412; called by muse, mutect2, varscan2
- PRKG1 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100909838; called by muse, mutect2
- PRPF3 | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61394907; called by muse, mutect2, varscan2
- PRPF38A | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV57122511; called by muse, mutect2, varscan2
- PRPF6 | c.2411T>A p.L804Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53871245; called by muse, mutect2, varscan2
- PRRC2B | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV61937530; called by muse, mutect2, varscan2
- PSG3 | c.1108G>C p.G370R | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV59504503, COSV59506533; called by muse, mutect2, varscan2
- PTCRA | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58975786; called by muse, mutect2, varscan2
- PTDSS1 | c.1012T>C p.Y338H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61264493; called by muse, mutect2, varscan2
- PTGS1 | c.1504T>A p.F502I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56292259; called by muse, mutect2
- PTK2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199666239, COSV61786263; called by muse, mutect2, varscan2
- PTPRD | c.4390A>G p.K1464E | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100647259; called by muse, mutect2
- PTPRF | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63445309; called by muse, mutect2, varscan2
- PXDN | c.2951T>C p.L984P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53234962; called by muse, mutect2, varscan2
- RAB13 | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63945267; called by muse, mutect2, varscan2
- RABEP2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs756554838, COSV62869614; called by muse, mutect2, varscan2
- RABGAP1L | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52297412; called by muse, mutect2, varscan2
- RAD18 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99368838; called by muse, mutect2
- RAI14 | c.2708A>G p.Q903R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54295182; called by muse, varscan2
- RALGAPA1 | c.4954A>G p.T1652A | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV51884107; called by muse, mutect2, varscan2
- RANBP10 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746228287, COSV100449502; called by muse, varscan2
- RANBP10 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58157956; called by muse, varscan2
- RASAL1 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55653504, COSV55656320; called by muse, mutect2, varscan2
- RASAL2 | c.2330A>G p.Q777R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV100862950; called by muse, mutect2, varscan2
- RBBP6 | c.1386+2T>A p.X462_splice | Splice Site (SNP) | VAF 14/88 reads (16%) | catalogued as COSV60505369; called by muse, mutect2, varscan2
- RBFOX1 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100303758; called by muse, mutect2, varscan2
- RBM11 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV68747909; called by muse, mutect2, varscan2
- RBM22 | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV52271571; called by muse, mutect2, varscan2
- RBM26 | c.1648A>C p.N550H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763682411, COSV57394937; called by muse, mutect2, varscan2
- RBSN | c.112T>G p.S38A | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53793249; called by muse, mutect2, varscan2
- RC3H1 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51201542, COSV99281579; called by muse, mutect2, varscan2
- RDX | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV58194099; called by muse, mutect2, varscan2
- RETSAT | c.1693+2T>C p.X565_splice | Splice Site (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99806309; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs762949421; called by mutect2, varscan2
- RGS7BP | c.638T>A p.L213* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV61835039; called by muse, mutect2, varscan2
- RHOBTB2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1404884399, COSV52570955; called by muse, mutect2, varscan2
- RHOBTB2 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV52570964; called by muse, mutect2, varscan2
- RIF1 | c.6699T>G p.S2233R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.235); catalogued as COSV54617585; called by muse, mutect2, varscan2
- RIOK1 | c.1491T>A p.D497E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99344932; called by muse, mutect2
- RIOX2 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV57724217; called by muse, mutect2, varscan2
- RIPK3 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV53475664; called by muse, mutect2, varscan2
- RLIM | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100223333; called by muse, mutect2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs760343057; called by mutect2, varscan2
- RMND5B | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51070998; called by muse, mutect2, varscan2
- RNASE6 | c.244A>G p.S82G | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV58977506; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF149 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54864067; called by muse, mutect2, varscan2
- RNF215 | c.1097A>T p.K366I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53176152; called by muse, mutect2, varscan2
- ROS1 | c.2794T>A p.S932T | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV63855348, COSV63855675; called by muse, mutect2, varscan2
- RPA4 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs752735862, COSV61270783, COSV61271012; called by muse, mutect2, varscan2
- RPGRIP1L | c.1505A>G p.H502R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50907495; called by muse, mutect2, varscan2
- RPL32 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV56233028; called by muse, mutect2, varscan2
- RPS18 | c.350T>A p.I117N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV65851632; called by muse, mutect2, varscan2
- RSBN1 | c.2110T>A p.Y704N | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54734410, COSV99793635; called by muse, mutect2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as rs759904440; called by mutect2, varscan2
- RUNDC3A | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs563233289, COSV56636952; called by muse, mutect2, varscan2
- RYR1 | c.8894G>A p.R2965H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV62098450; called by muse, mutect2, varscan2
- RYR2 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV100773112; called by muse, mutect2
- RYR2 | c.5858T>C p.M1953T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63687563; called by muse, mutect2, varscan2
- SACS | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV101207754; called by muse, mutect2
- SAE1 | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99538241; called by muse, mutect2
- SAGE1 | c.1711A>G p.T571A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.421); catalogued as COSV61013789; called by muse, mutect2, varscan2
- SAMD15 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV53626447; called by muse, mutect2, varscan2
- SAMD3 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.079); catalogued as COSV60775860; called by muse, mutect2, varscan2
- SAMD9 | c.4108A>G p.T1370A | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs774962440, COSV66075585; called by muse, mutect2, varscan2
- SAMD9 | c.3413A>G p.N1138S | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV66075597; called by muse, mutect2, varscan2
- SARS1 | c.1427T>A p.I476N | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV52320985; called by muse, mutect2, varscan2
- SATB1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV58669748; called by muse, mutect2, varscan2
- SATB1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.598); catalogued as rs1180700640, COSV100113488; called by muse, mutect2, varscan2
- SCARB1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs368337422; called by muse, mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN10A | c.3224C>G p.A1075G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV71861582; called by muse, mutect2, varscan2
- SCNN1B | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as rs370777535; called by muse, mutect2, varscan2
- SCUBE2 | c.2495A>G p.Q832R (on ENST00000649792 / NM_001367977.2; = p.Q775R on NM_020974.3) | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV58542996; called by muse, mutect2, varscan2
- SCYL1 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV54212855; called by muse, mutect2, varscan2
- SEC11A | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51613155, COSV51614224; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMG1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV54872937, COSV99725106; called by muse, mutect2, varscan2
- SEPTIN1 | c.1216del p.A406Pfs*60 (on ENST00000321367; = p.A359Pfs*60 on NM_052838.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV100363074; called by mutect2, pindel, varscan2
- SERAC1 | c.1684+2T>C p.X562_splice | Splice Site (SNP) | VAF 12/204 reads (6%) | catalogued as rs1274076957, COSV100894901; called by muse, mutect2
- SERPINB2 | c.767T>A p.L256H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs370190157, COSV55092711; called by muse, mutect2, varscan2
- SETD2 | c.5209A>G p.S1737G | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57438598; called by muse, mutect2, varscan2
- SF3A1 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV53169083; called by muse, mutect2, varscan2
- SF3A2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV55555004; called by muse, mutect2, varscan2
- SFTPB | c.73T>C p.W25R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1320815322, COSV60893404; called by muse, mutect2, varscan2
- SH3D19 | c.804T>C p.C268= | Splice Region (SNP) | VAF 61/169 reads (36%) | catalogued as rs748398926, COSV58790855; called by muse, mutect2, varscan2
- SH3PXD2B | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61127132; called by muse, mutect2, varscan2
- SIGLEC1 | c.409+2T>C p.X137_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99171247; called by muse, mutect2, varscan2
- SIRPB1 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 44/153 reads (29%) | catalogued as rs148690008; called by muse, mutect2, varscan2
- SLC15A3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV57171854; called by muse, mutect2, varscan2
- SLC16A7 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV53895287; called by muse, mutect2, varscan2
- SLC25A10 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58970581; called by muse, mutect2, varscan2
- SLC25A20 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); catalogued as COSV59803032; called by muse, mutect2, varscan2
- SLC2A4RG | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369712293; called by muse, mutect2, varscan2
- SLC35B3 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59468304; called by muse, mutect2, varscan2
- SLC35B4 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV65984798; called by muse, mutect2, varscan2
- SLC37A4 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV58155591; called by muse, mutect2, varscan2
- SLC38A9 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV59423784; called by muse, mutect2, varscan2
- SLC39A5 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.761); catalogued as COSV57191864; called by muse, mutect2, varscan2
- SLC45A2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99673231; called by muse, mutect2
- SLC4A7 | c.2021T>G p.F674C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55397856; called by muse, mutect2, varscan2
- SLC5A9 | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52583774; called by muse, mutect2, varscan2
- SLC6A2 | c.1231A>G p.M411V | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV54916828; called by muse, mutect2, varscan2
- SLC6A4 | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55567105; called by muse, mutect2, varscan2
- SLC9A7 | c.1459+2T>C p.X487_splice | Splice Site (SNP) | VAF 14/252 reads (6%) | catalogued as COSV100092813; called by muse, mutect2
- SMAP2 | c.682-1G>T p.X228_splice | Splice Site (SNP) | VAF 21/106 reads (20%) | catalogued as COSV65532447; called by muse, mutect2, varscan2
- SMARCA4 | c.2854del p.E952Kfs*5 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as COSV100759350; called by mutect2, pindel, varscan2
- SMCHD1 | c.3176A>G p.N1059S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55258161; called by muse, mutect2, varscan2
- SMCP | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.042); catalogued as COSV64217712; called by muse, mutect2, varscan2
- SMG1 | c.8152A>G p.N2718D | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV67171678; called by muse, mutect2, varscan2
- SMIM8 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs898996055, COSV57640296; called by muse, mutect2, varscan2
- SMPDL3A | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100868740; called by muse, mutect2
- SMYD1 | c.1411A>G p.M471V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs779040242, COSV70225218; called by mutect2, varscan2
- SNRNP200 | c.4201C>G p.L1401V | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.474); catalogued as COSV60490205; called by muse, mutect2, varscan2
- SOHLH2 | c.783G>C p.M261I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV65902277; called by muse, varscan2
- SOX6 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as COSV57045718, COSV57046945; called by muse, mutect2
- SPAG1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222655970, COSV52560195; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs750890082; called by mutect2, varscan2
- SPIN3 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1569325588, COSV100888503; called by muse, mutect2
- SPNS2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747757809, COSV61230460; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 50/180 reads (28%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPRED1 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100136447; called by muse, mutect2, varscan2
- SPTA1 | c.1741T>A p.S581T | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV63753869; called by muse, mutect2, varscan2
- SPTBN1 | c.1325A>C p.Q442P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61688955; called by muse, mutect2, varscan2
- SPTBN2 | c.6110G>A p.R2037H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs144215906; called by mutect2, varscan2
- SPTLC1 | c.887A>T p.N296I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV52764310; called by muse, mutect2, varscan2
- SPTLC3 | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65465891; called by muse, mutect2, varscan2
- SRRM2 | c.6323C>A p.A2108E | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV51940806; called by muse, mutect2, varscan2
- ST18 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs773799178, COSV99391178; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | PolyPhen benign (0.003); catalogued as COSV56571459; called by muse, mutect2, varscan2
- STAB1 | c.2631T>C p.A877= | Splice Region (SNP) | VAF 40/109 reads (37%) | catalogued as COSV58736853; called by muse, mutect2, varscan2
- STARD7 | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs773518469, COSV61525858; called by muse, mutect2, varscan2
- STK36 | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55326893; called by muse, mutect2, varscan2
- STOX1 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV53815069; called by muse, varscan2
- STX18 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs141662322; called by muse, mutect2, varscan2
- SUCO | c.3034A>C p.S1012R | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV55265670; called by muse, mutect2, varscan2
- SUGP1 | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55921874; called by muse, mutect2, varscan2
- SUN2 | c.1108T>A p.S370T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV53304194; called by mutect2, varscan2
- SUPT5H | c.1143+1G>C p.X381_splice | Splice Site (SNP) | VAF 35/133 reads (26%) | catalogued as COSV63239929; called by muse, mutect2, varscan2
- SUPT6H | c.3421T>C p.Y1141H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58927659; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP2L | c.2096A>C p.N699T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs1191757110, COSV99305893; called by muse, mutect2, varscan2
- SYN1 | c.2090A>T p.K697M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51692890; called by muse, mutect2, varscan2
- SYNCRIP | c.48T>A p.D16E | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV62287825; called by muse, mutect2, varscan2
- SYNE1 | c.5987A>G p.D1996G (on ENST00000367255 / NM_182961.4; = p.D2003G on NM_033071.3) | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54993426; called by muse, mutect2, varscan2
- SYNE2 | c.18851G>A p.R6284H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202157687, COSV59952208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYP | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781872198, COSV99603164; called by muse, mutect2
- TAAR1 | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs758707759, COSV51588690; called by mutect2, varscan2
- TANC1 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV55088764; called by muse, mutect2, varscan2
- TAOK1 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV99914832; called by muse, mutect2, varscan2
- TAS2R41 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV68765358; called by muse, mutect2, varscan2
- TASOR2 | c.1001_1003del p.K334del | In Frame Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs755383545; called by pindel, varscan2
- TASOR2 | c.3182A>G p.H1061R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV60167657; called by muse, mutect2, varscan2
- TATDN1 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52679631; called by muse, mutect2, varscan2
- TBATA | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV54719487; called by muse, mutect2, varscan2
- TBC1D12 | c.1732T>C p.Y578H | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56554450, COSV56554697; called by muse, mutect2, varscan2
- TBC1D15 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV59849524; called by muse, mutect2, varscan2
- TBC1D17 | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55578849; called by muse, mutect2, varscan2
- TCF12 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV51006975; called by muse, mutect2, varscan2
- TDRD5 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs775805075, COSV54243533; called by muse, mutect2, varscan2
- TECTA | c.1988A>C p.E663A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99881668; called by mutect2, varscan2
- TEKT2 | c.283-1G>C p.X95_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV52881036; called by muse, mutect2, varscan2
- TEKT5 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51589167; called by muse, mutect2, varscan2
- TGFBI | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as COSV59350695, COSV59351498; called by muse, mutect2, varscan2
- THAP1 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV54273185; called by muse, mutect2, varscan2
- THEMIS | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64071404; called by muse, mutect2, varscan2
- THNSL2 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs146704484; called by muse, mutect2, varscan2
- THRAP3 | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100663644; called by muse, mutect2
- TJAP1 | c.1424C>A p.P475H (on ENST00000372445 / NM_001146016.1; = p.P465H on NM_080604.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV52501148, COSV52503439; called by muse, mutect2, varscan2
- TJP2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55267510; called by muse, mutect2, varscan2
- TLN2 | c.1520A>G p.H507R | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs764083207, COSV60890142; called by muse, mutect2, varscan2
- TLN2 | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779849306, COSV60890149; called by muse, mutect2, varscan2
- TLR8 | c.424T>G p.S142A (on ENST00000218032 / NM_138636.5; = p.S160A on NM_016610.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV54318212; called by muse, mutect2, varscan2
- TMCC1 | c.1094T>C p.V365A (on ENST00000393238 / NM_001349268.2; = p.V41A on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100261342; called by muse, mutect2
- TMCO1 | c.410T>C p.V137A (on ENST00000612311 / NM_001256164.1; = p.V86A on NM_019026.6) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.469); catalogued as COSV63318286; called by muse, mutect2, varscan2
- TMEM117 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs772555669, COSV56898989, COSV56899483; called by muse, mutect2, varscan2
- TMEM131L | c.1308+2T>C p.X436_splice | Splice Site (SNP) | VAF 21/89 reads (24%) | catalogued as COSV53644871; called by muse, mutect2, varscan2
- TMEM169 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV55265370; called by muse, mutect2, varscan2
- TMEM19 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57000063; called by muse, mutect2, varscan2
- TMEM255A | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs782307217, COSV59029348; called by muse, mutect2, varscan2
- TMEM41A | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV99956722; called by muse, mutect2
- TMEM87A | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV67746974; called by muse, varscan2
- TNFAIP2 | c.1247C>A p.T416K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60694721; called by muse, mutect2, varscan2
- TNXB | c.13013A>G p.H4338R (on ENST00000647633; = p.H4091R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as rs1428522788, COSV64479663; called by mutect2, varscan2
- TNXB | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs534795841, COSV64479670; called by muse, mutect2, varscan2
- TOB1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs777982053, COSV99278954; called by muse, mutect2, varscan2
- TOMM40 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52985584; called by muse, mutect2, varscan2
- TONSL | c.2852+2T>C p.X951_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101340317; called by muse, mutect2, varscan2
- TPP1 | c.1526A>G p.Q509R | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs149529997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPR | c.3097-2A>G p.X1033_splice | Splice Site (SNP) | VAF 31/130 reads (24%) | catalogued as COSV100823565, COSV66601679; called by muse, mutect2, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 33/193 reads (17%) | catalogued as rs753514580; called by mutect2, varscan2
395 further variants in this file (144 protein-altering or splice-affecting, 235 silent, 16 other) are not listed here.
